Somatic mutation profile of tumor specimen TCGA-XK-AAIV-01A (aliquot TCGA-XK-AAIV-01A-11D-A41K-08) from TCGA case TCGA-XK-AAIV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.9 years (23,325 days).
Specimen TCGA-XK-AAIV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 838ba210-deab-423d-a6b8-b9ad0d08498b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XK-AAIV-10A (Blood Derived Normal), aliquot TCGA-XK-AAIV-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f4b61b5-7429-4054-afc1-129cb2630918

The open-access MAF lists 44 somatic variants for this specimen: 36 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 5, RNA 2, Nonsense Mutation 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.5028G>T p.L1676F | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV99661204; called by muse, mutect2
- BACH2 | c.46T>A p.S16T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100001207; called by muse, mutect2, varscan2
- CCDC116 | c.727T>G p.S243A | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV99489021; called by muse, mutect2, varscan2
- CENPL | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100616443; called by muse, mutect2, varscan2
- DIAPH1 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1014304479, COSV99526077; called by muse, mutect2
- DNAH9 | c.2997G>A p.M999I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99308469; called by muse, mutect2, varscan2
- DOP1B | c.782A>T p.D261V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.21); catalogued as COSV101215872; called by muse, mutect2, varscan2
- FLT3 | c.1442G>C p.G481A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99610381; called by muse, mutect2, varscan2
- FRAS1 | c.6183C>A p.H2061Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.769); catalogued as rs780449619, COSV99356163; called by muse, mutect2, varscan2
- GCM1 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV99452683; called by mutect2, varscan2
- GTPBP10 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1056459314, COSV55988712; called by muse, mutect2
- HOXA3 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV100415732; called by muse, mutect2, varscan2
- INO80 | c.3158G>T p.G1053V | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100732095; called by muse, mutect2
- IRF4 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1270389563, COSV101110970; called by muse, mutect2, varscan2
- KIF18B | c.1591G>A p.D531N (on ENST00000593135 / NM_001265577.2; = p.D543N on NM_001264573.2) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775862605, COSV100192659; called by mutect2, varscan2
- LTBP4 | c.1008A>C p.R336S (on ENST00000308370 / NM_001042544.1; = p.R299S on NM_003573.2) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99199720; called by muse, mutect2
- MRGPRX1 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.075); catalogued as rs770746594, COSV100246173; called by muse, mutect2, varscan2
- NALCN | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51942581, COSV51953892; called by muse, mutect2, varscan2
- NUDT7 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs765625065, COSV51744464; called by muse, mutect2, varscan2
- NUP160 | c.3397C>T p.R1133* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as rs373754603, COSV65854876; called by muse, mutect2
- NYAP2 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311059994, COSV56017053; called by muse, mutect2, varscan2
- OR10J1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71128701; called by muse, mutect2, varscan2
- PARD3 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100402135; called by muse, mutect2, varscan2
- PCDHGA11 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1404612424, COSV99545143, COSV99548109; called by muse, mutect2
- PDE12 | c.1614C>A p.F538L | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV100239991; called by muse, mutect2, varscan2
- PKD2L2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV99296752; called by muse, mutect2
- PLA2G4D | c.1589T>C p.I530T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1475547920, COSV99300103; called by muse, mutect2
- PPP1R42 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV61206692; called by muse, mutect2, varscan2
- RAD54B | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 69/171 reads (40%) | catalogued as rs377463964; called by muse, mutect2, varscan2
- RTF1 | c.1277T>A p.L426Q | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101048282; called by muse, mutect2, varscan2
- S100A7A | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV100241694; called by muse, mutect2, varscan2
- SETD4 | c.1189G>C p.V397L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV100145776; called by muse, varscan2
- SORCS1 | c.2411C>T p.T804M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773906334, COSV53877562; called by muse, mutect2
- TASOR2 | c.7049A>G p.N2350S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.249); catalogued as COSV100051156; called by muse, mutect2, varscan2
- WDR33 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1352061629, COSV100460743; called by muse, mutect2, varscan2
- EAPP | c.30_31insA p.Y11Ifs*4 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel, varscan2
- ABCA13 | c.993C>T p.C331= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- CD63 | c.114C>T p.V38= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV99141887; called by muse, mutect2, varscan2
- CDHR2 | c.1125C>T p.Y375= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs141872147; called by muse, mutect2, varscan2
- MPZL2 | c.99G>T p.R33= | Silent (SNP) | VAF 12/195 reads (6%) | catalogued as COSV99635345; called by muse, mutect2
- ZNF878 | c.381C>T p.S127= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV101521265; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840523 C>T | 5'Flank (SNP) | VAF 7/71 reads (10%) | catalogued as rs148044699, COSV58327449, COSV58329360; called by muse, mutect2
- BTN2A3P | n.190C>T | RNA (SNP) | VAF 9/70 reads (13%) | catalogued as rs538897008; called by muse, mutect2, varscan2
- SNORD116-6 | n.29del | RNA (DEL) | VAF 39/284 reads (14%) | called by mutect2, pindel, varscan2
